Surgical pathology report (de-identified scan), TCGA case TCGA-BF-AAP7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-AAP7-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** Female

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

Gross description:

The material presented – skin flap from right leg

Microscopic description:

skin-fascial flap 11x9x2 cm tumor in the center of a mushroom-shaped dark brown depth of 1 cm, rises above the surface to 0.5 cm Epithelioid pigmented melanoma with ulceration, Breslow - 5 mm, Clark – IV

Final diagnosis: Epithelioid cell melanoma

ICD-O-3
Melanoma, epithelioid cell 8721/3
Site: Skin (R) leg C44.7
Q15 4/22/14

Confidential

Dual/Synchronous History		

Source: NCI Genomic Data Commons file 039a1229-c5f8-47a8-ae4c-f6fa27c300ee (TCGA-BF-AAP7.7AC6ABBA-DA58-4361-B349-19F950959BA3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).